Somatic mutation profile of tumor specimen TARGET-10-PASTHE-09A (aliquot TARGET-10-PASTHE-09A-01D) from TARGET case TARGET-10-PASTHE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.4 years (2,327 days).
Specimen TARGET-10-PASTHE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 712309c4-5433-4f48-b4ae-289bf363ed0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASTHE-10A (Blood Derived Normal), aliquot TARGET-10-PASTHE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56929c35-450a-40b5-9549-803a17cb5cfc

The open-access MAF lists 54 somatic variants for this specimen: 32 protein-altering or splice-affecting, 16 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 16, Frame Shift Ins 4, Nonsense Mutation 4, Intron 3, 3'UTR 2, Splice Site 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 28/62 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CDA | c.359C>A p.P120Q | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.541); catalogued as COSV66751441; called by muse, mutect2
- CDS1 | c.469T>C p.F157L | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.791); catalogued as COSV55686950; called by muse, mutect2, varscan2
- CHRM2 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs768531848, COSV57767335, COSV57769152; called by muse, mutect2, varscan2
- CLEC17A | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 26/65 reads (40%) | catalogued as rs759035385, COSV60427019; called by muse, mutect2, varscan2
- DNAH1 | c.5479C>T p.R1827C | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs765753155, COSV70226796; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGD1 | c.964G>T p.V322F | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.66); PolyPhen benign (0.086); catalogued as COSV64308215; called by muse, mutect2, varscan2
- IGF2BP1 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as COSV51729716; called by muse, mutect2, varscan2
- IHH | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.999); catalogued as rs572724795, COSV55392878; called by muse, mutect2, varscan2
- IKZF2 | c.1558C>T p.R520* | Nonsense Mutation (SNP) | VAF 27/51 reads (53%) | catalogued as rs867974779, COSV59577002; called by muse, mutect2, varscan2
- KRT75 | c.168C>A p.S56R | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV52871368; called by muse, mutect2, varscan2
- MTMR9 | c.584dup p.N195Kfs*41 | Frame Shift Ins (INS) | VAF 38/106 reads (36%) | catalogued as rs767880823; called by mutect2, varscan2
- NOTCH1 | c.4793G>C p.R1598P | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.918); catalogued as COSV53027279, COSV53097635; called by muse, mutect2, varscan2
- PDE1C | c.267G>T p.E89D | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.07); catalogued as rs760789343, COSV58505617; called by muse, mutect2, varscan2
- PHF6 | c.902A>G p.Y301C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV59700182; called by muse, mutect2, varscan2
- PKD1L1 | c.1543G>T p.G515* | Nonsense Mutation (SNP) | VAF 48/88 reads (55%) | catalogued as COSV56959650; called by muse, mutect2, varscan2
- RNF24 | c.361C>A p.P121T | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV60191176; called by muse, mutect2, varscan2
- RPL22 | c.35dup p.K13Qfs*12 | Frame Shift Ins (INS) | VAF 17/57 reads (30%) | catalogued as rs752855455; called by mutect2, pindel, varscan2
- RPL5 | c.706-2A>G p.X236_splice | Splice Site (SNP) | VAF 9/19 reads (47%) | catalogued as COSV59872958; called by muse, mutect2, varscan2
- SIK3 | c.1433A>T p.Q478L (on ENST00000445177 / NM_001366686.2; = p.Q484L on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV52610303; called by muse, mutect2, varscan2
- TBC1D16 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.541); catalogued as rs777552860, COSV60476041; called by muse, mutect2, varscan2
- TDRD6 | c.2495A>G p.Q832R | Missense Mutation (SNP) | VAF 138/299 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV60174288; called by muse, mutect2, varscan2
- TNFRSF10A | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs773006381, COSV55324773; called by muse, mutect2, varscan2
- TRAP1 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs368889500, COSV55915197; called by muse, mutect2, varscan2
- TUBA3D | c.590A>G p.H197R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as rs751200552; called by muse, mutect2, varscan2
- UNC13C | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.902); catalogued as rs1359672529, COSV52843724; called by muse, mutect2, varscan2
- ZNF667 | c.754G>T p.V252F | Missense Mutation (SNP) | VAF 23/310 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV52631917; called by muse, mutect2
- ZNF732 | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs782807148; called by muse, mutect2
- C2CD2 | c.1585_1586insGCAATTGAGGACG p.A529Gfs*3 | Nonsense Mutation (INS) | VAF 15/64 reads (23%) | called by mutect2, pindel, varscan2
- CDKN1B | c.285del p.G97Vfs*22 | Frame Shift Del (DEL) | VAF 38/105 reads (36%) | called by mutect2, pindel, varscan2
- EWSR1 | c.250dup p.Q84Pfs*16 | Frame Shift Ins (INS) | VAF 27/93 reads (29%) | called by mutect2, pindel, varscan2
- EWSR1 | c.1076_1077insTCAGTCCCTTCTTTGA p.N360Qfs*5 | Frame Shift Ins (INS) | VAF 11/28 reads (39%) | called by mutect2, pindel, varscan2
- ALPG | c.84G>A p.P28= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as rs1351342028; called by muse, mutect2, varscan2
- ATP2B4 | c.186T>C p.P62= | Silent (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- BCL9 | c.738G>A p.Q246= | Silent (SNP) | VAF 98/212 reads (46%) | called by muse, mutect2, varscan2
- CCM2 | c.99T>C p.H33= | Silent (SNP) | VAF 67/143 reads (47%) | called by muse, mutect2, varscan2
- CYRIA | c.873C>T p.A291= | Silent (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- GPR50 | c.957C>T p.F319= | Silent (SNP) | VAF 7/121 reads (6%) | called by muse, mutect2
- GRM7 | c.1908C>A p.I636= | Silent (SNP) | VAF 74/168 reads (44%) | called by muse, mutect2, varscan2
- ILF3 | c.1641C>T p.T547= | Silent (SNP) | VAF 37/115 reads (32%) | catalogued as rs552623942; called by muse, mutect2, varscan2
- KRTAP13-1 | c.429C>T p.G143= | Silent (SNP) | VAF 62/127 reads (49%) | catalogued as rs565845316, COSV62662638; called by muse, mutect2, varscan2
- PCDHB2 | c.564C>T p.L188= | Silent (SNP) | VAF 52/120 reads (43%) | catalogued as rs782227382, COSV52033782, COSV99523045; called by muse, mutect2, varscan2
- PRB3 | c.27C>T p.A9= | Silent (SNP) | VAF 52/142 reads (37%) | called by muse, varscan2
- SLITRK2 | c.2043C>T p.D681= | Silent (SNP) | VAF 60/135 reads (44%) | catalogued as rs182696674, COSV59425016; called by muse, mutect2, varscan2
- TLR8 | c.1380G>A p.E460= (on ENST00000218032 / NM_138636.5; = p.E478= on NM_016610.4) | Silent (SNP) | VAF 36/239 reads (15%) | called by muse, mutect2, varscan2
- TNFRSF11A | c.660C>T p.F220= | Silent (SNP) | VAF 18/216 reads (8%) | catalogued as rs534076974; called by muse, mutect2
- UNC80 | c.690C>T p.T230= | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as rs199927612, COSV55897980; called by muse, mutect2, varscan2
- ZNF292 | c.5106A>G p.V1702= | Silent (SNP) | VAF 59/118 reads (50%) | called by muse, mutect2, varscan2
- GRXCR1 | c.*69T>A | 3'UTR (SNP) | VAF 17/43 reads (40%) | catalogued as rs796495255, COSV67673441; ClinVar: uncertain significance; called by muse, mutect2
- PLD4 | c.468+79G>A | Intron (SNP) | VAF 8/17 reads (47%) | catalogued as rs781075101; called by muse, mutect2, varscan2
- RNF217-AS1 | n.1266C>A | RNA (SNP) | VAF 53/111 reads (48%) | called by muse, mutect2, varscan2
- STEAP1 | c.762+946G>T | Intron (SNP) | VAF 53/144 reads (37%) | called by muse, mutect2, varscan2
- TCP10L2 | c.657+19G>A | Intron (SNP) | VAF 27/61 reads (44%) | called by muse, mutect2, varscan2
- ZNF140 | c.*42dup | 3'UTR (INS) | VAF 31/86 reads (36%) | catalogued as rs773874866; called by mutect2, pindel
